TCGA case TCGA-05-4384 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9a50e7e4-831d-489f-87d2-979e987561cc

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 66 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,411 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Vinorelbine; Days to treatment start: 61 days; Days to treatment end: 153 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 183 days; Days to treatment end: 214 days; Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Zoledronic Acid; Days to treatment start: 245 days; Days to treatment end: 426 days (1.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 395 days (1.1 years); Days to treatment end: 426 days (1.2 years); Treatment outcome: Progressive Disease.
2. Prior malignancy of the bladder (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the rectum (histology not recorded by GDC). AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Metastasis of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 67.3 years (24,594 days); Days to diagnosis: 183 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (2 entries)
- Day 183 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 183 days.
- Days to follow up: 426 days (1.2 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 1987.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-05-4384-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-05-4384-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5.
  Slide TCGA-05-4384-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 7.
- Sample TCGA-05-4384-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-05-4384-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Malignant neoplasm of rectum.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -1553.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder; Other malignancy histological type: Malignant neoplasm of bladder.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -92.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy rectal cancer. Prior malignancy bladder cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 426 days; disease-specific survival: no event (censored), 426 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 183 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-05-4384-01A-01D-1752-01): tumor purity 0.49, ploidy 2.03, whole-genome doublings 0.
